Somatic mutation profile of tumor specimen MMRF_2093_1_BM_CD138pos (aliquot MMRF_2093_1_BM_CD138pos_T1_KHS5U_L08098) from MMRF case MMRF_2093, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.2 years (18,691 days).
Specimen MMRF_2093_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35e8d5a0-8895-40f6-90b0-b740100a7484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2093_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2093_1_PB_Whole_C2_KHS5U_L08099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42daae7d-468d-45fd-9487-7134a7da0e30

The open-access MAF lists 115 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 25, Silent 18, Intron 12, 5'UTR 5, Nonsense Mutation 4, 5'Flank 4, RNA 3, 3'Flank 3, Splice Site 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCKR | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | catalogued as rs375836361, CM104743; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 69/142 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APBB1IP | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1218916907; called by muse, mutect2
- ARMC9 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754901782; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs780519643, COSV100772001; called by muse, mutect2, varscan2
- CSRNP2 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1400690969; called by muse, mutect2
- GCC2 | c.3565G>T p.E1189* | Nonsense Mutation (SNP) | VAF 4/63 reads (6%) | catalogued as COSV59173862; called by muse, mutect2
- GCM2 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs536827295; called by muse, mutect2, varscan2
- IGHJ6 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 32/62 reads (52%) | PolyPhen benign (0); catalogued as rs376921777; called by muse, varscan2
- IGLV4-60 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV66503392, COSV66503398; called by muse, mutect2, varscan2
- ITGA2B | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs753409781, CD021198, CD061427, COSV52235917, COSV99288665; called by muse, mutect2, varscan2
- KIF2B | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as rs770787002, COSV52130448; called by muse, mutect2, varscan2
- MAP1A | c.7063G>C p.E2355Q | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as COSV100289253; called by muse, mutect2, varscan2
- MS4A2 | c.13A>C p.S5R | Missense Mutation (SNP) | VAF 129/298 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs371027336; called by muse, mutect2, varscan2
- NPLOC4 | c.1696C>T p.L566F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs1024339446; called by muse, mutect2
- OR4M1 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 231/732 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as COSV60063054; called by muse, mutect2, varscan2
- PIWIL3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as COSV59998549; called by muse, mutect2, varscan2
- PREX2 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55790417; called by muse, mutect2, varscan2
- PXYLP1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 136/241 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201734068, COSV53892056; called by muse, mutect2, varscan2
- PYROXD2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs139454799; called by muse, mutect2, varscan2
- RFTN1 | c.826+1G>C p.X276_splice | Splice Site (SNP) | VAF 49/103 reads (48%) | catalogued as rs199528537; called by muse, mutect2, varscan2
- SYT10 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs866619464, COSV57342184; called by muse, mutect2, varscan2
- ADGRL1 | c.3051C>T p.V1017= (on ENST00000340736 / NM_001008701.3; = p.V1012= on NM_014921.5) | Splice Region (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- ARMCX4 | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BAIAP2L2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- BBS12 | c.-8C>T | Splice Region (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- DUSP28 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2
- DZIP3 | c.531T>A p.F177L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FRY | c.4423-2A>T p.X1475_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, varscan2
- H4C5 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HUWE1 | c.9508G>A p.D3170N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2
- IGLV3-10 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, varscan2
- KCNK2 | c.124A>G p.T42A (on ENST00000444842 / NM_001017425.3; = p.T27A on NM_014217.4) | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- MERTK | c.2771C>A p.P924H | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NID2 | c.1945C>G p.Q649E | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- PAPPA | c.3494G>T p.S1165I | Missense Mutation (SNP) | VAF 178/345 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PPFIA2 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIDT2 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- SOAT1 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 78/128 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D4 | c.128_129dup p.S44Gfs*40 | Frame Shift Ins (INS) | VAF 57/87 reads (66%) | called by pindel, varscan2
- UNC5D | c.1880G>T p.S627I | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- WDR20 | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ZFHX4 | c.6529T>G p.F2177V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF587B | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- BSN | c.5751C>T p.F1917= | Silent (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- CHDH | c.489C>T p.C163= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CNOT1 | c.4476T>C p.A1492= | Silent (SNP) | VAF 79/155 reads (51%) | catalogued as rs756413479; called by muse, mutect2, varscan2
- CPXM2 | c.789C>G p.P263= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs141382056, COSV99582808; called by muse, mutect2, varscan2
- FBXO22 | c.201C>T p.T67= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs778035636; called by muse, mutect2, varscan2
- HCRTR2 | c.1323T>G p.L441= | Silent (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- HLA-A | c.9C>A p.V3= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as rs751579782, COSV65142684; called by muse, mutect2
- HPCAL4 | c.9G>A p.K3= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- KLRG2 | c.729G>A p.E243= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- MAIP1 | c.145T>C p.L49= | Silent (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- MCM6 | c.972C>T p.S324= | Silent (SNP) | VAF 203/442 reads (46%) | called by muse, mutect2, varscan2
- MSH3 | c.33C>T p.L11= | Silent (SNP) | VAF 114/226 reads (50%) | catalogued as rs564921007, COSV54150487, COSV54152343; called by muse, mutect2, varscan2
- PHF6 | c.933T>G p.A311= | Silent (SNP) | VAF 163/337 reads (48%) | called by muse, mutect2, varscan2
- ROBO1 | c.3996C>T p.D1332= | Silent (SNP) | VAF 28/348 reads (8%) | catalogued as rs780966134, COSV71393859; called by muse, mutect2
- SKOR2 | c.174G>T p.G58= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- TEK | c.2808G>C p.L936= | Silent (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2, varscan2
- VCAN | c.5544T>G p.T1848= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- VKORC1 | c.387T>C p.Y129= | Silent (SNP) | VAF 104/222 reads (47%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822459 A>C | 5'Flank (SNP) | VAF 6/115 reads (5%) | called by muse, mutect2
- ARHGAP6 | c.589-11241A>C | Intron (SNP) | VAF 92/207 reads (44%) | catalogued as rs1344897369; called by muse, mutect2, varscan2
- ASXL1 | c.*1232A>T | 3'UTR (SNP) | VAF 39/138 reads (28%) | called by muse, mutect2, varscan2
- BCL2 | c.-65G>A | 5'UTR (SNP) | VAF 109/231 reads (47%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021411 G>C | 5'Flank (SNP) | VAF 59/121 reads (49%) | catalogued as COSV55846921, COSV55847077; called by muse, mutect2, varscan2
- BLACE | n.1948C>A | RNA (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+3155dup | Intron (INS) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- CIT | c.*188C>T | 3'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- COBL | c.*710G>A | 3'UTR (SNP) | VAF 34/63 reads (54%) | catalogued as rs920497626; called by muse, mutect2, varscan2
- CUX1 | c.*1010G>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | catalogued as rs1409932749, COSV52909572; called by muse, varscan2
- DNAI4 | c.1097-465T>G | Intron (SNP) | VAF 81/156 reads (52%) | called by muse, mutect2, varscan2
- EIF3F | chr11:7986943 A>G | 5'Flank (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691023 del T | 3'Flank (DEL) | VAF 28/64 reads (44%) | catalogued as rs920483656; called by mutect2, pindel, varscan2
- GGCTP1 | n.279A>C | RNA (SNP) | VAF 60/186 reads (32%) | called by muse, mutect2, varscan2
- GPAT4 | c.*3113G>A | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, varscan2
- H2BC21 | c.*1483C>T | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- HMGN2 | c.237+171G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs1002694048; called by muse, mutect2, varscan2
- KDM3B | c.4412-39A>C | Intron (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2
- LRCH3 | c.-16T>C | 5'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+36512C>T | Intron (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- MIR5195 | n.101C>G | RNA (SNP) | VAF 25/53 reads (47%) | catalogued as rs529696904; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851196 ins GATGGTTAC | 5'Flank (INS) | VAF 32/148 reads (22%) | called by pindel, varscan2
- MMP17 | c.160-73G>A | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*955A>C | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- NEXMIF | c.*2473C>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- NRL | c.*160C>T | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- NSUN4 | c.-219C>A | 5'UTR (SNP) | VAF 8/169 reads (5%) | called by muse, mutect2
- PARP8 | c.*1831T>C | 3'UTR (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- PAX6 | chr11:31789892 T>A | 3'Flank (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1169G>A | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- PIKFYVE | c.*846T>C | 3'UTR (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
- POR | c.*15T>G | 3'UTR (SNP) | VAF 78/144 reads (54%) | called by muse, mutect2, varscan2
- PYGO1 | c.*5414A>C | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- RAB1B | c.*388C>T | 3'UTR (SNP) | VAF 7/201 reads (3%) | called by muse, mutect2
- RAB3GAP2 | c.115+17808C>G | Intron (SNP) | VAF 13/373 reads (3%) | called by muse, mutect2
- SGK2 | c.653+78C>A | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2
- SH2D5 | c.*806T>G | 3'UTR (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- SMYD5 | c.*668C>T | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15972153 A>T | 3'Flank (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- SP5 | c.-114G>T | 5'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- SYT7 | c.*1198C>A | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- TGFB1I1 | c.*233C>T | 3'UTR (SNP) | VAF 53/202 reads (26%) | catalogued as rs767032545; called by muse, mutect2, varscan2
- TGS1 | c.-125G>C | 5'UTR (SNP) | VAF 84/167 reads (50%) | catalogued as rs1051046030; called by muse, mutect2
- TLR10 | c.*310A>G | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, varscan2
- TMEM176B | c.*101C>T | 3'UTR (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- VMA21 | c.*1143A>C | 3'UTR (SNP) | VAF 55/115 reads (48%) | catalogued as rs997553465; called by muse, mutect2, varscan2
- WDR26 | c.*3297T>C | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- XIAP | c.*3212T>G | 3'UTR (SNP) | VAF 31/59 reads (53%) | catalogued as COSV63022615; called by muse, mutect2, varscan2
- ZDHHC19 | c.408+79G>T | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2
- ZFP82 | c.*344T>C | 3'UTR (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- ZMYM6 | c.428+577G>A | Intron (SNP) | VAF 7/119 reads (6%) | catalogued as rs879851550; called by muse, mutect2
- ZNF483 | c.722-2181G>C | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
